Somatic mutation profile of tumor specimen TCGA-D1-A1O0-01A (aliquot TCGA-D1-A1O0-01A-11D-A17D-09) from TCGA case TCGA-D1-A1O0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 77.1 years (28,162 days).
Specimen TCGA-D1-A1O0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae0dc964-25a9-413d-8118-339075fab3d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1O0-10A (Blood Derived Normal), aliquot TCGA-D1-A1O0-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8f0c856-2f84-4d0d-821f-c08d164d0466

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 15, Nonsense Mutation 3, Frame Shift Del 2, Splice Site 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as rs137852424, CM900089, CM990550, COSV100811708; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 78/88 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.1594G>A p.V532M | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99183886; called by muse, mutect2, varscan2
- AFF2 | c.3814+1G>T p.X1272_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as rs782699057, COSV53982796; called by muse, mutect2
- BST1 | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1379012280, COSV99400081; called by muse, mutect2, varscan2
- CATSPERB | c.1588-2A>G p.X530_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99831548; called by muse, mutect2, varscan2
- CCDC9B | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1186329775, COSV66875510; called by muse, mutect2, varscan2
- CERT1 | c.1665G>A p.M555I (on ENST00000405807 / NM_001130105.1; = p.M427I on NM_005713.3) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99783540; called by muse, mutect2, varscan2
- CHD4 | c.3440C>G p.A1147G (on ENST00000357008 / NM_001363606.2; = p.A1160G on NM_001273.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100538662, COSV58893847; called by muse, mutect2, varscan2
- CPAMD8 | c.3142G>A p.V1048I (on ENST00000651564; = p.V1001I on NM_015692.5) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs374273186; called by muse, mutect2, varscan2
- CTNNA3 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs369033938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP1A2 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.046); catalogued as COSV100673921, COSV59659924; called by muse, mutect2, varscan2
- CYP2B6 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs34284776, COSV100137682; called by muse, mutect2, varscan2
- CYP7B1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100042497, COSV59598067; called by muse, mutect2, varscan2
- DCDC1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV100663921; called by muse, mutect2, varscan2
- EPB41L4B | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs781369450, COSV65797013; called by muse, mutect2, varscan2
- FAM131C | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as COSV100989740; called by muse, mutect2, varscan2
- FAM133A | c.112A>G p.R38G | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV100220557; called by muse, mutect2
- FRY | c.4774A>G p.I1592V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs768682879, COSV100969695; called by muse, mutect2, varscan2
- HCFC1 | c.2203A>G p.I735V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.194); catalogued as COSV100129583; called by muse, mutect2, varscan2
- LRRC32 | c.1900T>C p.F634L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99477149; called by muse, mutect2, varscan2
- MIOX | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs145084575; called by muse, mutect2, varscan2
- NAPA | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs775030966, COSV54550935; called by muse, mutect2, varscan2
- NDUFS8 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs754342395, COSV50290012; called by muse, mutect2, varscan2
- NEK2 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65355185; called by muse, mutect2, varscan2
- NELFCD | c.811G>A p.A271T (on ENST00000602795; = p.A253T on NM_198976.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.354); catalogued as rs766644663, COSV100682931; called by muse, mutect2, varscan2
- NT5C1B | c.1222T>A p.C408S (on ENST00000359846 / NM_001199086.2; = p.C348S on NM_033253.4) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV100410193; called by muse, mutect2, varscan2
- PALD1 | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as COSV99698525; called by muse, varscan2
- PAPOLG | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 22/43 reads (51%) | catalogued as COSV53181672; called by muse, mutect2, varscan2
- PKD1L1 | c.4595G>A p.G1532D | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.412); catalogued as COSV99220854; called by muse, mutect2, varscan2
- PLPPR2 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs139320193; called by muse, mutect2, varscan2
- PPM1H | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as COSV99956256; called by muse, mutect2, varscan2
- PPP2R1A | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV59044929; called by muse, mutect2, varscan2
- SALL2 | c.2789A>G p.Q930R | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV100444528; called by muse, mutect2, varscan2
- SLC22A7 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV101000846; called by muse, mutect2, varscan2
- SLC35D1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs776653054, COSV99338419; called by muse, mutect2, varscan2
- TENM4 | c.5440C>T p.R1814C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs912426848, COSV53613100; called by muse, mutect2, varscan2
- TIMM21 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99400167; called by muse, mutect2, varscan2
- TRPV5 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV99520831; called by muse, mutect2, varscan2
- TSGA10 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs923653988, COSV100747696, COSV61824855; called by muse, mutect2, varscan2
- ULBP1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 44/322 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99997973, COSV99998251; called by muse, mutect2, varscan2
- ZFYVE16 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs1561268609, COSV100566579; called by muse, mutect2, varscan2
- TINF2 | c.1198_1201del p.E400Mfs*21 | Frame Shift Del (DEL) | VAF 31/70 reads (44%) | called by mutect2, pindel, varscan2
- TRIM31 | c.917del p.N306Tfs*7 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- ATP1A4 | c.1662T>C p.G554= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV100927613; called by muse, mutect2, varscan2
- CACNA1F | c.3363C>T p.I1121= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV100545173; called by muse, mutect2, varscan2
- CCT2 | c.99C>T p.I33= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs780733349, COSV54741127; called by muse, mutect2, varscan2
- EGR2 | c.769C>A p.R257= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as rs368282744, COSV54346517; called by muse, mutect2, varscan2
- HDLBP | c.2076G>A p.V692= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100191443; called by muse, mutect2, varscan2
- HELB | c.2494C>T p.L832= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV99922095; called by muse, mutect2, varscan2
- PCDHGA8 | c.1794G>A p.S598= | Silent (SNP) | VAF 61/167 reads (37%) | catalogued as rs769750411, COSV53921015; called by muse, mutect2, varscan2
- PRKD3 | c.885C>G p.L295= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV99306489; called by muse, mutect2, varscan2
- RIMS2 | c.4497G>A p.T1499= (on ENST00000666250 / NM_001348490.2; = p.T1070= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 60/108 reads (56%) | catalogued as rs759228374, COSV51667612, COSV51667933; called by muse, mutect2, varscan2
- SP3 | c.1467G>A p.L489= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100022110; called by muse, mutect2, varscan2
- SPATA31A1 | c.1770A>T p.P590= | Silent (SNP) | VAF 24/61 reads (39%) | called by mutect2, varscan2
- SPTBN5 | c.10809C>T p.H3603= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs374980494; called by muse, mutect2, varscan2
- SYNE1 | c.20757C>A p.V6919= (on ENST00000367255 / NM_182961.4; = p.V6848= on NM_033071.3) | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs1490654093, COSV99573450; called by muse, mutect2, varscan2
- TOP1MT | c.967C>T p.L323= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as COSV100239599; called by muse, mutect2, varscan2
- WDR6 | c.1692C>G p.P564= | Silent (SNP) | VAF 61/86 reads (71%) | catalogued as COSV100556637; called by muse, mutect2, varscan2
- KMT2C | c.11670+988G>A | Intron (SNP) | VAF 15/16 reads (94%) | catalogued as rs371760883; called by muse, mutect2, varscan2
- ZNF208 | c.*482C>T | 3'UTR (SNP) | VAF 27/58 reads (47%) | catalogued as rs369562799, COSV68101968; called by muse, mutect2, varscan2
